Surgical pathology report (de-identified scan), TCGA case TCGA-05-4398, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4398-01A (Primary Tumor).

Main diagnosis/diagnoses:

Locally advanced, peripheral bronchopulmonary, histologically mixed adenocarcinoma of the right upper lobe of the lung with a predominant large-cell, polymorphocellular and partly clear-cell solid component, with bronchioloalveolar growth pattern in the tumor periphery and very small acinar part, mainly located in S1 and satellite focus in S3.

TNM classification pT4 pN3 L1 V1 R0, stage IIIB

C 34.1 M 8255/3

Comment/supplementary remark:

The main tumor shows a large cicatricial area and has invaded small blood vessels located in the tumor and also lymph nodes. There are lymph node metastases in samples 1.) to 4.), 6.) to 8.) and 10.). The visceral pleura and resection margins of the bronchus and vessels of the main preparation and also the lymph nodes of samples 5.) to 9.) are tumor-free.

Source: NCI Genomic Data Commons file 005cf956-54cd-4129-bdee-cbe537d904ce (TCGA-05-4398.37D9EE69-F24E-4DDA-A283-078243DB1FA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).